Somatic mutation profile of tumor specimen TCGA-N7-A4Y5-01A (aliquot TCGA-N7-A4Y5-01A-12D-A28R-08) from TCGA case TCGA-N7-A4Y5, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Age at diagnosis: 87.8 years (32,058 days).
Specimen TCGA-N7-A4Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7380e297-f677-41d0-b11b-d998f99b0fd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N7-A4Y5-10A (Blood Derived Normal), aliquot TCGA-N7-A4Y5-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc2b013-e9cc-4df7-869e-097e9d751c3a

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Splice Site 4, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 34/53 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.712T>C p.C238R | Missense Mutation (SNP) | VAF 44/50 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519981, CM025271, CM056070, COSV52699956, COSV52707471, COSV52711035, COSV52711932; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP11B | c.2318T>G p.L773R | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60032480; called by muse, mutect2, varscan2
- CASZ1 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as rs1388895000; called by muse, mutect2, varscan2
- FFAR3 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 61/262 reads (23%) | catalogued as rs1568498358; called by muse, mutect2, varscan2
- GPR20 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1165866327; called by muse, mutect2
- KMT2D | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as rs774098338; called by muse, mutect2, varscan2
- MYO7B | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as rs866741397; called by muse, mutect2, varscan2
- NLRP1 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV52574016; called by muse, mutect2, varscan2
- NUP50 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs926954823; called by mutect2, varscan2
- OBSCN | c.15604G>A p.E5202K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755758580, COSV99480483; called by muse, varscan2
- OR4K2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV53848232; called by muse, mutect2, varscan2
- OR51A7 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV63788777; called by muse, mutect2, varscan2
- OR9Q2 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs904149485, COSV100285520; called by muse, mutect2, varscan2
- PCDHA2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.024); catalogued as COSV65368199; called by muse, mutect2
- PCDHB6 | c.1949G>C p.R650P | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.196); catalogued as COSV50719581; called by muse, mutect2, varscan2
- PDE4D | c.970C>G p.R324G (on ENST00000340635 / NM_001104631.2; = p.R188G on NM_006203.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57718441; called by muse, mutect2, varscan2
- POLR1A | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796614841; called by muse, mutect2, varscan2
- RNF43 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1193652088; called by muse, mutect2, varscan2
- SH3TC1 | c.1961G>C p.R654P | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV55283524, COSV55283764; called by muse, mutect2, varscan2
- STEAP4 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57331699; called by muse, mutect2, varscan2
- TENM3 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.622); catalogued as rs755138158; called by muse, mutect2, varscan2
- UQCRC1 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT tolerated (0.41); PolyPhen benign (0.181); catalogued as rs759346286; called by muse, mutect2, varscan2
- VWA5A | c.1473C>G p.I491M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as COSV64414246; called by muse, mutect2, varscan2
- ABCA12 | c.2032A>C p.N678H (on ENST00000272895 / NM_173076.3; = p.N360H on NM_015657.3) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP35 | c.3827-2_3830del p.X1276_splice | Splice Site (DEL) | VAF 17/30 reads (57%) | called by mutect2, pindel, varscan2
- B3GLCT | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CEP41 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- CRTAM | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FBN2 | c.4051del p.H1351Tfs*8 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- H2BC11 | c.235_236insA p.S79Yfs*39 | Frame Shift Ins (INS) | VAF 107/216 reads (50%) | called by mutect2, pindel, varscan2
- HSPA1B | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.041); called by mutect2, varscan2
- ICAM4 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- KIF5A | c.2495T>G p.F832C | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP10 | c.902C>G p.T301S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBD1 | c.1405G>C p.V469L (on ENST00000269468 / NM_001323950.1; = p.V413L on NM_002384.2) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MFSD3 | c.831-1G>A p.X277_splice | Splice Site (SNP) | VAF 172/336 reads (51%) | called by muse, mutect2, varscan2
- MOGAT2 | c.650+2T>C p.X217_splice | Splice Site (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- MYO1B | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRSS12 | c.1195C>G p.R399G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIPPLY3 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SACS | c.9697A>G p.K3233E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM131 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TMEM97 | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- XKR4 | c.971T>G p.I324S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF107 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF782 | c.118_142+21del p.X40_splice | Splice Site (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- ANGPTL2 | c.1236C>T p.N412= | Silent (SNP) | VAF 101/202 reads (50%) | catalogued as rs759995472, COSV52233319; called by muse, mutect2, varscan2
- BRINP3 | c.1926G>A p.E642= | Silent (SNP) | VAF 102/108 reads (94%) | catalogued as rs774769622; called by muse, mutect2, varscan2
- CHST10 | c.525T>C p.I175= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- FGF10 | c.519G>T p.G173= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as COSV99241058; called by muse, mutect2, varscan2
- KCNC4 | c.330C>T p.Y110= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs752096441; called by muse, mutect2, varscan2
- MGAT5 | c.141C>T p.R47= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs760320533; called by muse, mutect2, varscan2
- NPR3 | c.603A>C p.A201= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- NRXN2 | c.1113C>T p.N371= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs201527514; called by muse, mutect2, varscan2
- OPRM1 | c.258C>T p.F86= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- OR2C1 | c.786G>A p.P262= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs376908052; called by muse, varscan2
- PAX7 | c.741C>T p.R247= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs148641282, COSV64752979; called by muse, mutect2, varscan2
- PLCB4 | c.420C>T p.N140= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs761440267; called by muse, varscan2
- RC3H1 | c.3279A>G p.T1093= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs184786158; called by muse, mutect2, varscan2
- SLC8A1 | c.2799C>T p.I933= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs373502373, COSV60477959; called by muse, mutect2, varscan2
- SPATA5 | c.720G>T p.L240= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- SRPK1 | c.1728G>C p.V576= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- TRADD | c.396G>A p.E132= | Silent (SNP) | VAF 22/23 reads (96%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.250-13036C>G | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99790914; called by muse, mutect2, varscan2
- RPS12 | c.131+283_131+284del | Intron (DEL) | VAF 5/23 reads (22%) | catalogued as rs1339005816; called by mutect2, pindel, varscan2
